Gene-level copy-number profile of specimen HCM-CSHL-0600-C25-85A from HCMI case HCM-CSHL-0600-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.7 years (26,567 days).
Specimen HCM-CSHL-0600-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c63d4452-9f5a-4ad2-b594-259750fc4609.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0600-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/3d8c8ed4-ac20-438b-9f98-5e2b9f8368f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,844; copy number 2: 45,723; copy number 3: 1,236; copy number 4: 42; copy number 5: 9; copy number 6: 38; copy number 7: 1; copy number 10: 13; copy number 18: 9; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:22,088,060–25,953,468, 70 genes, copy number 5–25 (broad region; genes not listed).
- chr18:29,518,259–29,548,241, 1 gene, copy number 7: AC117569.1.

Autosomal genes at a single copy (total copy number 1): 8,988. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
